Surgical pathology report (de-identified scan), TCGA case TCGA-85-A513, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A513-01A (Primary Tumor).

UID: 47BESF80-C50E-4892-B0F9-7F93E73D356B

Gross Description: Tumor is located in left sublobe IV, ill - margins with 1.5x1.5x2cm in size, firm and white-gray surface.

Microscopic Description: Tumor tissue arranges in the form of group or sheets or trabeculae or adenoids of tumor cells. The malignant cells have moderate, eosinophilic cytoplasm. The nuclei are enlarged, single or multiple, variability in size and shape, containing coarse clumped

Diagnosis Details: Squamous cell carcinoma, Grade III

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

ICD-0-3

Specimen type: Pneumonectomy

Tumor site: Lung

Carcinoma, Squamous cell, NOS 8070/3
Site: Lung, Upper lobe c34.1

Tumor size: 1.5 x 1.5 x 2 cm

lw
11/8/12

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Present

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Left- upper

Source: NCI Genomic Data Commons file 93671c2c-5739-4eca-9339-7b50b5eed3c4 (TCGA-85-A513.47BE5F80-C50E-4B92-B0F9-7F93E73D356B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).